Surgical pathology report (de-identified scan), TCGA case TCGA-VP-A875, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Washington University, specimen TCGA-VP-A875-01A (Primary Tumor).

[page 1 of 3]
Patient Name: [REDACTED]

Surgical Pathology Report

Final

ICD-0-3
Adenocarcinoma, acinar
8140/3
Site Prostate NOS
C61.9
Q411.2/13

SURGICAL PATHOLOGY REPORT FINAL

Patient Name: [REDACTED]

Address: [REDACTED]

Gender: M

Service: [REDACTED]

Location: [REDACTED]

MRN: [REDACTED]

Hospital #: [REDACTED]

Patient Type: [REDACTED]

Accession #: [REDACTED]

Other Related Clinical Data:

DIAGNOSIS:

PROSTATE, LAPAROSCOPIC EXCISION

- ADENOCARCINOMA, GLEASON GRADE 3+4, RIGHT AND LEFT LOBES, 10% OF GLAND, T3a/N0/MX (STAGE III)
- FOCAL EXTRAPROSTATIC EXTENSION PRESENT IN THE RIGHT APEX
- INKED MARGINS FREE OF TUMOR
- PERINEURAL INVASION PRESENT
- SEMINAL VESICLES FREE OF TUMOR
- LYMPH NODES, PELVIC, SIDE NOT SPECIFIED, EXCISION
- FOUR LYMPH NODES WITH NO EVIDENCE OF MALIGNANCY (0/4)

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By
Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and is interpreted as: "Specimen weight 48.5 grams. Tissue sent for tumor bank."

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis.

History:

The patient is a [REDACTED] with a history of prostate adenocarcinoma, Gleason Grade 3+4, with perineural invasion [REDACTED]. Operative procedure: Laparoscopic prostatectomy and pelvic lymph node excision.

Specimen(s) Received:

A: PROSTATE

B: LYMPH NODES, PELVIC

[page 2 of 3]
Patient Name: [REDACTED]

Gross Description

The specimens are received in two formalin-filled containers, each labeled "[REDACTED]". The first container is labeled "prostate." It holds a prostate with one attached left seminal vesicle, and one detached right seminal vesicle. The prostate has previously been inked black, and has had sections removed from both the right and left lobe. The prostate weighs 48.5 gm and measures 4.7 cm from anterior to posterior, 4.8 cm from superior to inferior, and 5.3 cm from left to right. The right seminal vesicle measures 2.7 x 1.6 x 1.4 cm; the left seminal vesicle measures 2.2 x 1.7 x 0.9 cm. On section, the prostate shows soft, pink-tan, unremarkable tissue and the seminal vesicles are unremarkable. Labeled A1 - shaved bladder neck margin; A2 and A3 - left apical radial margin; A4 and A5 - right apical radial margin; A6 and A7 - left apex; A8 and A9 - right apex; A10 and A11 - left base; A12 and A13 - right base; A14 - left seminal vesicle; A15 - right seminal vesicle. Jar 1. The second container is labeled "lymph nodes pelvic." It contains a mass of fibrofatty tissue with a diameter of 2.8 cm in diameter, measured in aggregate. Labeled B1, B2 Jar 0

SYNOPTIC WORKSHEET - PROSTATE CARCINOMA

NEOPLASM

A neoplasm is present

HISTOPATHOLOGIC TYPE

The tumor type is adenocarcinoma, acinar type

INTRAGLANDULAR TUMOR EXTENT

The intraglandular tumor extent (reported as percent of prostate gland involved by carcinoma) = 10% (crude visual estimate)

GLEASON'S GRADE

The Gleason's Grade is 3+4

TUMOR LOCATION

The location of the tumor involves the
right base
right apex
left apex

PERINEURAL INVASION

Perineural Invasion is identified

VASCULAR INVASION

Vascular Invasion is not identified

EXTRAPROSTATIC EXTENSION

Extraprostatic (extracapsular) extension is present
The tumor extends into the periprostatic soft tissues (specify site): Right apex

SEMINAL VESICLES

Seminal vesicles are free of tumor

SAMPLED SPECIMEN MARGINS

All sampled surgical margins are free of tumor

[page 3 of 3]
Patient Name: [REDACTED]

NON-NEOPLASTIC PROSTATE

The non-neoplastic prostate shows no abnormalities

METASTATIC LYMPH NODES

The lymph nodes are as follows (expressed as the number of metastatic nodes in relation to the total number of nodes examined)

"pelvic" (0/4)

PRIMARY TUMOR (T)

Tumor extends through the prostate capsule (T3)

Extracapsular extension (unilateral or bilateral) (T3a)

REGIONAL LYMPH NODES (N)

No regional lymph node metastasis (N0)

DISTANT METASTASIS

Distant metastasis cannot be assessed (not evaluated by any modality) (MX)

STAGE GROUPING

T3a/N0/MX (Gleason Grade 3+4) (Stage III)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

	Yes	No

Source: NCI Genomic Data Commons file 7b0a40c9-4b08-47ec-9c1c-5d6cdf794ee3 (TCGA-VP-A875.2CF80467-58E9-4A65-94D5-08401BE6ACB5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).